Somatic mutation profile of tumor specimen MP2PRT-PASUEB-TBP1-A (aliquot MP2PRT-PASUEB-TBP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASUEB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.1 years (6,263 days).
Specimen MP2PRT-PASUEB-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 296ac196-a2a4-4072-8329-c001d19ccf5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASUEB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASUEB-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0d7b9af-59a5-48f3-88a3-7f73f7f0a648

The open-access MAF lists 16 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 14, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.182A>T p.D61V | Missense Mutation (SNP) | VAF 51/335 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs121918461, CM013415, CM098208, COSV61004983, COSV61005256, COSV61011211; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD4 | c.2335C>T p.R779W (on ENST00000357008 / NM_001363606.2; = p.R792W on NM_001273.5) | Missense Mutation (SNP) | VAF 59/416 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58901404; called by muse, mutect2, varscan2
- COL1A2 | c.3487T>G p.C1163G | Missense Mutation (SNP) | VAF 62/259 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM088552; called by muse, mutect2, varscan2
- JRK | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 112/373 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70630546; called by muse, mutect2, varscan2
- LRFN5 | c.564G>T p.K188N | Missense Mutation (SNP) | VAF 37/504 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV53272079; called by muse, mutect2
- NT5C1B | c.545C>T p.S182L (on ENST00000359846 / NM_001199086.2; = p.S122L on NM_033253.4) | Missense Mutation (SNP) | VAF 44/584 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1356733805, COSV100409892; called by muse, mutect2
- OCA2 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 49/333 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs151118268; called by muse, mutect2, varscan2
- PPP1R26 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 44/412 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as rs372323498; called by muse, mutect2, varscan2
- UMOD | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 36/459 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs965326455; called by muse, mutect2
- CRACD | c.2416C>G p.P806A | Missense Mutation (SNP) | VAF 36/496 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- EOLA2 | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 22/652 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- HOXA3 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 25/689 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- OPRPN | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 94/437 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- REX1BD | c.203dup p.L69Pfs*26 | Frame Shift Ins (INS) | VAF 114/419 reads (27%) | called by mutect2, pindel, varscan2
- RPS6KA3 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 46/316 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.314); called by muse, mutect2
- ELOVL2 | c.669C>T p.A223= | Silent (SNP) | VAF 42/504 reads (8%) | catalogued as rs368259009; called by muse, mutect2
